Surgical pathology report (de-identified scan), TCGA case TCGA-G9-6377, project TCGA-PRAD (Prostate Adenocarcinoma), tissue source site Roswell Park, specimen TCGA-G9-6377-01A (Primary Tumor).

[page 1 of 2]
SPECIMENS:

- A. LEFT PELVIC LYMPH NODES
- B. RIGHT PELVIC LYMPH NODES
- C. PROSTATE

TCGA-G9-6377

SPECIMEN(S):

- A. LEFT PELVIC LYMPH NODES
- B. RIGHT PELVIC LYMPH NODES
- C. PROSTATE

INTRAOPERATIVE CONSULTATION DIAGNOSIS:

FSA1-FSA3/ FSB1-FSB2: Left and right pelvic lymph nodes: No tumor seen.
Diagnoses called by Dr. to Dr. [REDACTED]

GROSS DESCRIPTION:

A. LEFT PELVIC LYMPH NODE

Received fresh labeled with the patient's identification and "left pelvic lymph node" are multiple pieces of fatty tissue in aggregate, 5.8 x 4.5 x 0.8 cm containing two lymph nodes, 0.5 x 0.3 x 0.2 cm(1) and 3.5 x 1 x 0.3 cm(2); touch preps are performed and the lymph nodes are submitted entirely for frozen section diagnosis:

FSA1: lymph node 1

FSA2-FSA3: lymph node 2

B. RIGHT PELVIC LYMPH NODES

Received fresh labeled with the patient's identification and "right pelvic lymph nodes" are multiple pieces of fatty tissue in aggregate, 5.5 x 3.6 x 1 cm. Six possible lymph nodes are identified ranging from 0.5 to 2.5 cm. Lymph nodes are submitted entirely for frozen section diagnosis:

FSB1: largest lymph node

FSB2: 5 possible smaller lymph nodes

C. PROSTATE

Received fresh labeled with the patient's identification and "prostate" is a 39-g resected prostate gland measuring 4.2 cm from left lateral to right lateral, 3.8 cm from anterior to posterior, and 3.5 cm from apex to base. The capsule is smooth, red, and intact. Ink code: Anterior-orange, apex-red, base-blue, right lateral-green, left lateral-yellow, posterior-black. After removal of apex to base, the prostate weighs 21 g; it has a nodular tan parenchyma. The right seminal vesicle is 3.5 x 2.6 x 0.9 cm and the left is 4 x 1.2 x 0.7 cm; they consist of cystic tan tissue. The right vas deferens is 2.7 x 0.5 cm and the left is 1.9 x 0.6 cm; they consist of tubular tan tissue. Tissue is procured (10g). Submitted entirely:

C1: right apex, perpendicular sections

C2: left apex, perpendicular sections

C3: level 1, anterior and right lateral capsule

C4: level 1, posterior and left lateral capsule

C5: level 2, right anterior

C6: level 2, right posterior

C7: level 2, left anterior

C8: level 2, left posterior

C9: level 3, anterior and right lateral capsule

C10-C11: level 3, posterior and left lateral capsule

C12-C13: right mid base, perpendicular sections

C14-C15: left mid base, perpendicular sections

C16-C17: right lateral base, perpendicular sections

C18-C19: left lateral base, perpendicular sections

C20: base with root of right seminal vesicle and vas deferens

C21: base with root of left seminal vesicle and vas deferens

C22: right seminal vesicle and vas deferens

C23: left seminal vesicle and vas deferens

DIAGNOSIS:

A. LEFT PELVIC LYMPH NODES, EXCISION:

- TWO (2) LYMPH NODES AND ASSOCIATED FIBROADIPOSE TISSUE, NEGATIVE FOR TUMOR

B. RIGHT PELVIC LYMPH NODES, EXCISION:

- FOUR (4) LYMPH NODES AND THE ASSOCIATED FIBROADIPOSE TISSUE, NEGATIVE FOR TUMOR

[page 2 of 2]
C. PROSTATE, SEMINAL VESICLES, AND VASA DEFERENTIA (RADICAL PROSTATECTOMY):

- PROSTATIC ADENOCARCINOMA, GLEASON SCORE 3 + 4 = 7 INVOLVING THE LEFT AND RIGHT PROSTATE LOBES, LIMITED TO THE PROSTATE
- TUMOR INVOLVES LESS THAN 10% OF PROSTATE TISSUE
- PERINEURAL INVASION IDENTIFIED
- NO ANGIOLYMPHATIC INVASION IDENTIFIED
- NO EXTRAPROSTATIC EXTENSION IDENTIFIED
- LEFT AND RIGHT SEMINAL VESICLES AND VAS DEFERENS, NEGATIVE FOR TUMOR
- SEE SYNOPTIC REPORT

SYNOPTIC REPORT - PROSTATE GLAND

Specimens Involved

Specimens: A: LEFT PELVIC LYMPH NODES

B: RIGHT PELVIC LYMPH NODES

C: PROSTATE

Location: Left

Right

Posterior lateral

Apical

Basal

Anterior

WHO CLASSIFICATION

Epithelial tumors

Adenocarcinoma 8140/3

Multicentricity: Yes

Gland Involvement: 10%

Gleason Grade/Sum:: Grade 3 + 4 , Sum 7

High Grade PIN Present: Yes

Perineural Invasion: Yes

Vascular/Lymphatic Invasion: No

Seminal Vesicle Invasion: No

Periprostic Fat Involved: No

Bladder Neck Involved: No

Margins Involvement: No

Frozen Performed: No

Lymph Nodes: Negative Right 0 / 4 Left 0 / 2

Other Pathologic Findings: BPH

Pathological Staging (pTNM): T 2c N 0 M x

Pathological staging is based on the AJCC Cancer Staging Manual, 7th Edition

pT2c: Tumor involves both lobes

pMX: Cannot be assessed

CLINICAL HISTORY:

None given

PRE-OPERATIVE DIAGNOSIS:

Prostate cancer

Source: NCI Genomic Data Commons file 56ad98d0-0410-4f92-a4a2-e8f5de49c658 (TCGA-G9-6377.520ABBF9-817A-45DB-AECC-22C4FC80DDAE.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).